Surgical pathology report (de-identified scan), TCGA case TCGA-HC-8262, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-8262-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

DIAGNOSIS

DIAGNOSIS:

- A. Bilateral pelvic lymph nodes, biopsy:
Eight lymph nodes; negative for metastatic tumor (0/8).
- B. Left lateral margin, biopsy:
Benign fibrovascular tissue with nerve bundles and fibromuscular tissue; negative for malignancy.
- C. Prostate gland, radical prostatectomy:
Tumor Characteristics:
1. Histologic type: Adenocarcinoma.
2. Prostate size: 5.0 x 3.1 x 3.0 cm.
3. Tumor quantitation: Tumor involves both lobes and less than 5% of the tissue sampled.
4. Gleason grade:
- a. Primary pattern: 4/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 8/10.
5. Extraprostatic extension: No.
6. Seminal vesicle involvement: No.
7. Lymphovascular space invasion: No, however, tumor is present in a perivascular pattern, but no intraluminal neoplasm is seen.
8. High grade PIN: Yes.
9. Treatment effect: No.
10. Perineural invasion: Yes.
- Surgical Margin Status:**
1. Margins uninvolved: Apical, bladder, and prostatic soft tissue margins are all negative.
2. Margins involved: Closest margin is 1.5 mm from right posterior mid prostate margin.
- Lymph node Status:**
1. Total number received: Eight.
2. Number with metastatic carcinoma: Zero (0/8).
- Other:**
1. Other significant findings:
- a. Benign prostatic hyperplasia and high-grade PIN.
2. pTNM stage: T2c Nx Mx.

Electronic Signature: [REDACTED]

COMMENTS:

The tumor is predominantly Gleason 4, with a small focus of Gleason 3.

CLINICAL INFORMATION

CLINICAL HISTORY:

Preoperative Diagnosis: Prostate cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

- A. Bilateral pelvic lymph nodes
- B. Left lateral margin
- C. Prostate gland

SPECIMEN DATA

GROSS DESCRIPTION:

The specimen is received in three formalin filled containers labeled with the patient's name

[REDACTED]

[page 2 of 2]
Container A is additionally labeled "pelvic lymph nodes bilateral" and contains eight firm fatty possible lymph nodes ranging from 0.3 up to 2.7 cm in greatest dimension. They are entirely submitted in cassettes A1-3 labeled designated as follows: A1 four whole possible lymph nodes; A2 three whole possible lymph nodes; A3 one whole possible bisected lymph node.

Container B is additionally labeled "left lateral margin" and contains a 1.7 x 0.9 x 0.9 cm, pink-tan, rubbery soft tissue bearing a white clip. The clip is removed and the soft tissue is wrapped in filter paper and entirely submitted in cassette B labeled

Container C is additionally labeled "#3" and contains a 28.2 gm, 5.0 x 3.1 x 3.0 cm prostate received with partially attached bilateral adnexa which has overall dimensions of 3.0 x 2.5 x 0.7 cm. The part of the adnexa free-floating in the container is a convoluted pink-tan soft tissue consistent with seminal vesicle having overall dimensions of 3.0 x 1.5 x 0.5 cm. The prostatic capsule is pink-tan and shaggy. The specimen is inked as follows: right side blue and left side black. The base and apical margins are coned and serially sectioned. The remainder of the specimen is serially sectioned from apex to base to reveal a pink-tan, focally cystic cut surface with diffuse periurethral nodularity. A discrete mass is not identified however the tissue is focally indurated in the left posterior quadrant. Representative sections are submitted in cassettes C1-18 labeled designated as follows: 1 right prostate/seminal vesicle junction; 2 left prostate/seminal vesicle junction; 3-4 apical margin, perpendicular; 5-6 base or margin, perpendicular; 7-9 right anterior, apex to base; 10-12 right posterior, apex to base; 13-15 left anterior, apex to base; 16-18 left posterior, apex to base. Additionally, a yellow, green and blue cassette are submitted for genomics research, each labeled [REDACTED]

Source: NCI Genomic Data Commons file 12311aa0-0b1d-4ba0-bd47-2fb927f96982 (TCGA-HC-8262.B2B40B37-FCEE-4AD0-AE88-0CA54E39CF7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).